Surgical pathology report (de-identified scan), TCGA case TCGA-24-1548, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1548-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL

24-1548

*** Converted Case * This report may not match the original report format**

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- ~~POORLY DIFFERENTIATED SEROUS CARCINOMA~~
- EXTENSIVE LYMPHVASCULAR INVASION PRESENT

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- ~~POORLY DIFFERENTIATED SEROUS CARCINOMA~~
- EXTENSIVE LYMPHVASCULAR INVASION PRESENT

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED CARCINOMA, BY DIRECT EXTENSION
AS WELL AS SEROSAL METASTASIS
- HYDROSALPINX

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED CARCINOMA IN PERITUBAL SOFT
TISSUE, AS WELL AS ON SEROSAL SURFACE

OMENTUM, EXCISION

- METASTATIC POORLY DIFFERENTIATED CARCINOMA
(SEE COMMENT)

UTERUS, CERVIX, HYSTERECTOMY

- SEROSAL POORLY DIFFERENTIATED CARCINOMA
(POSTERIOR SURFACE)
- ENDOMETRIOSIS

UTERUS, ENDOMETRIUM, HYSTERECTOMY

- ENDOMETRIAL POLYP
- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

Microscopic Description and Comment:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Histologic examination shows a poorly differentiated serous carcinoma which involves both the right and left ovaries. Tumor is identified on the surfaces of both ovaries microscopically. Tumor also involves the right fallopian tube by direct extension as well as by serosal metastasis and is found in the serosal tissue adjacent to the left fallopian tube. Tumor is seen diffusely throughout the omental specimen (which measures 35 cm in greatest dimension) and therefore, the maximum size of the extrapelvic tumor implant must be measured at 35 cm.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
(Not applicable)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is: TUMOR DIFFUSELY INVOLVES THE ENTIRE OMENTAL SPECIMEN (35cm in greatest dimension)
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0 (zero).
18. The total number of metastatically-involved regional lymph nodes is 0 (zero).
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver.

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
3c	(T3c/ NX/ MX) IIIC

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History:

The patient is a [REDACTED] with an adnexal mass. Clinical diagnosis: Probable ovarian carcinoma. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, and omentectomy.

Specimen(s) Received:

A: OMENTUM

B: UTERUS, CERVIX, BOTH TUBES AND OVARIES

[page 3 of 4]
Gross Description:

The specimens are received in two containers of formalin, each labelled with the patient's name. The first is labelled "uterus, cervix, both tubes and ovaries." It contains an hysterectomy specimen with attached cervix, bilateral fallopian tubes and ovaries. The uterus measures 8.5 x 5.0 x 4.5 cm in greatest dimension and has a smooth, unremarkable serosal surface. The cervix measures 3.0 cm in length and 3.0 cm in greatest diameter and contains a circular os measuring 0.3 cm in greatest diameter. The uterus is bivalved in the coronal plane to show an unremarkable endocervical canal measuring 2.5 cm in length and 0.3 cm in greatest diameter. The endometrial cavity is smooth, tan-white, and measures 2.0 cm x 3.0 cm. It shows a polyp measuring 3.5 x 1.4 x 0.5 cm, which appears to have filled the majority of the endometrial cavity. The polyp is attached by a thin stalk (measuring 0.3 cm in greatest diameter) to the posterior aspect of the endometrial cavity. The right fallopian tube measures 4.0 cm in length and 0.5 cm in greatest diameter. It is densely adherent to an irregular multilobulated firm, white mass which is grossly suspicious for tumor and measures 3.0 x 2.0 x 1.5 cm in greatest dimension. This mass is partially adherent to the presumed normal ovary which measures 2.3 x 1.2 x 1.0 cm. The mass appears to grossly invade the fallopian tube but not the ovary. The left fallopian tube measures 4.0 cm in length and 0.5 cm in greatest diameter. It is externally grossly unremarkable. However, on sectioning, a firm, white nodule measuring 1.5 cm in greatest dimension is noted directly adjacent to the tube. However, it does not grossly appear to invade the fallopian tube. The left ovary is firm, yellow-white, and multilobulated, measuring 4.5 x 3.0 x 3.5 cm. The ovary appears to have had tissue excised prior to receipt. On cross section, the ovary is solid, firm, white with an area of central degeneration measuring 1.0 x 2.0 x 0.5 cm in greatest dimension. The ovarian serosa is smooth and the tumor appears grossly contained by it. Labelled A1, anterior cervix; A2, posterior cervix; A3, anterior endomyometrium; A4, posterior endomyometrium with endometrial polyp; A5, A6, right fallopian tube with tumor; A7, A8, right ovary and tumor; A9, left fallopian tube with tumor nodule; A10-A12, left ovarian tumor without residual normal ovary. Jar 2.

The second container is labelled "omentum." It contains a single irregular shaped fragment of fibrofatty tissue measuring 35 x 9 x 5.0 cm in greatest dimension. Serial sections through the omentum show that it is grossly diffusely involved by tumor. No distinct nodules are identified. Labelled B1, B2, sections of omentum with tumor. Jar 2.

Source: NCI Genomic Data Commons file 11556535-bfb7-4295-b79a-bcd4c86c6479 (TCGA-24-1548.D7B9BC71-E243-478F-A116-7E9371B87327.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).